Gene-level copy-number profile of specimen HCM-BROD-0458-C15-85N from HCMI case HCM-BROD-0458-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 57.6 years (21,052 days).
Specimen HCM-BROD-0458-C15-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83d069e4-2605-4b41-9f7b-d794b468d473.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0458-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/48b51ffa-967a-4d46-817f-a0f34f990a13

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 305; copy number 1: 4,311; copy number 2: 32,469; copy number 3: 15,270; copy number 4: 5,499; copy number 5: 322; copy number 6: 317; copy number 7: 139; copy number 8: 65; copy number 9: 8; copy number 10: 2; copy number 11: 18; copy number 12: 1; copy number 13: 23; copy number 14: 46; copy number 15: 18; copy number 16: 8; copy number 17: 25; copy number 18: 4; copy number 19: 2; copy number 24: 28.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,333,644–12,333,693, 1 gene: RNA5SP254.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,026 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:31,400,497–45,895,970, 237 genes, copy number 5–6 (broad region; genes not listed).
- chr6:38,675,925–42,217,861, 89 genes, copy number 5–19 (broad region; genes not listed).
- chr8:104,590,733–106,060,524, 12 genes, copy number 5 (within-gene range 4–5): ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24.
- chr8:128,405,269–128,564,679, 1 gene, copy number 5: LINC00824.
- chr9:32,783,540–34,546,996, 79 genes, copy number 7–16 (broad region; genes not listed).
- chr9:39,072,767–39,288,315, 5 genes, copy number 7: CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P.
- chr9:93,121,496–93,148,556, 2 genes, copy number 5: NINJ1, AL390760.1.
- chr9:93,318,199–93,453,581, 5 genes, copy number 5 (within-gene range 4–5): C9orf129, RNU6-829P, Y_RNA, AL583839.1, FAM120AOS.
- chr9:94,030,794–95,517,057, 42 genes, copy number 5 (within-gene range 4–5): PTPDC1, CYCSP24, MIRLET7A1HG, MIRLET7A1, MIRLET7F1, LINC02603, MIRLET7D, ZNF169, VDAC1P11, NUTM2F, AL691447.2, AL691447.1, PTMAP12, MFSD14B, YRDCP1, AL358232.2, AL358232.1, RNU6-669P, PCAT7, FBP2, FBP1, AOPEP, MIR2278, AL807757.1, AL807757.2, AL353768.1, AL353768.2, MIR6081, MIR23B, MIR27B, MIR3074, MIR24-1, FANCC, AL354893.2, AL354893.1, RNA5SP288, AL157384.1, AL161729.3, MT1P1, PTCH1, AL161729.2, AL161729.1.
- chr9:96,065,740–96,147,856, 4 genes, copy number 5: AL449403.1, Y_RNA, AL449403.2, EIF4BP3.
- chr9:99,183,373–99,185,866, 2 genes, copy number 5: AL162427.1, RN7SL794P.
- chr9:99,821,855–99,974,534, 3 genes, copy number 5: NR4A3, STX17, AL358937.1.
- chr9:100,427,143–101,325,135, 10 genes, copy number 5 (within-gene range 4–5): MSANTD3, MSANTD3-TMEFF1, TMEFF1, CAVIN4, RN7SKP87, ACTG1P19, AL162395.1, GAPDHP26, PLPPR1, AL161631.1.
- chr9:102,055,252–102,055,741, 1 gene, copy number 5: ARL2BPP7.
- chr9:102,922,574–102,923,244, 1 gene, copy number 5: AL365396.1.
- chr9:103,361,952–104,329,396, 6 genes, copy number 5: AL390962.1, RNA5SP291, SMC2-AS1, SMC2, TOPORSLP, AL512646.1.
- chr9:104,927,553–104,928,892, 1 gene, copy number 5 (within-gene range 4–5): AL359182.1.
- chr9:105,244,622–105,439,171, 1 gene, copy number 5: SLC44A1.
- chr9:106,615,078–106,615,983, 1 gene, copy number 5: AL512649.2.
- chr9:106,863,166–108,254,820, 25 genes, copy number 5 (within-gene range 4–5): ZNF462, AL807761.4, AL512593.1, AL807761.1, AL807761.2, AL807761.3, AL445487.1, RAD23B, LINC01509, AL359552.1, HMGN2P32, RNU6-492P, KLF4, AL389915.1, PPIAP88, RNU6-996P, RNU6-1064P, RN7SL659P, RPL36AP6, AL162389.1, RNA5SP293, RPS15AP27, AC068050.1, CHCHD4P2, AL353742.1.
- chr9:110,303,476–111,670,229, 22 genes, copy number 5: TXNDC8, SVEP1, RNU6-1039P, AL592463.1, MUSK, AL513328.1, LPAR1, RNU6-432P, Y_RNA, RNY4P18, AL162414.1, MIR7702, OR2K2, ECPAS, RNA5SP294, ZNF483, PTGR1, AL135787.1, LRRC37A5P, DNAJC25, DNAJC25-GNG10, GNG10.
- chr9:112,217,716–112,669,397, 10 genes, copy number 5: PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28, AL359073.1, HSDL2, C9orf147, KIAA1958, AL445187.1.
- chr9:114,323,056–114,326,475, 1 gene, copy number 5: ORM1.
- chr9:122,370,530–122,402,906, 3 genes, copy number 5: PTGS1, AL162424.1, AL359636.1.
- chr9:127,224,265–127,393,660, 3 genes, copy number 5: GARNL3, AL450263.2, AL445222.1.
- chr9:128,720,870–128,810,430, 5 genes, copy number 5 (within-gene range 1–5): ZDHHC12, AL441992.1, ZER1, Metazoa_SRP, TBC1D13.
- chr9:131,852,928–134,521,442, 68 genes, copy number 5–7 (broad region; genes not listed).
- chr9:136,107,808–136,766,255, 40 genes, copy number 5–6: LINC02846, TMEM250, AL138781.1, LHX3, QSOX2, CCDC187, CR392000.1, DKFZP434A062, GPSM1, DNLZ, CARD9, SNAPC4, ENTR1, PMPCA, INPP5E, SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15.
- chr9:137,306,896–138,253,217, 25 genes, copy number 8–9: EXD3, NOXA1, ENTPD8, NSMF, MIR7114, PNPLA7, MRPL41, DPH7, ZMYND19, ARRDC1, AL590627.2, ARRDC1-AS1, EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr10:50,623,466–52,298,423, 20 genes, copy number 7 (within-gene range 2–7): SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T.
- chr10:78,696,062–80,941,201, 67 genes, copy number 7 (broad region; genes not listed).
- chr11:77,066,961–78,444,049, 40 genes, copy number 5–7 (within-gene range 1–7): CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728.
- chr12:24,810,024–26,833,194, 45 genes, copy number 11–24: BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2.
- chr12:27,466,810–29,340,980, 39 genes, copy number 6–7 (within-gene range 2–19): SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2.
- chr17:31,008,154–31,093,127, 3 genes, copy number 5 (within-gene range 2–5): AC138207.3, AC138207.8, AC138207.6.
- chr17:38,530,031–39,927,601, 69 genes, copy number 5–6 (broad region; genes not listed).
- chr17:59,281,130–59,892,945, 17 genes, copy number 6: SNRPGP17, YPEL2, AC091059.2, MIR4729, AC091059.1, LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2.
- chr18:22,164,886–22,228,029, 6 genes, copy number 6: GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2.
- chr20:41,178,448–41,317,672, 1 gene, copy number 8 (within-gene range 4–8): ZHX3.
- chr20:41,290,280–42,063,969, 14 genes, copy number 8: RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3.

Autosomal genes at a single copy (total copy number 1): 2,287. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
